Somatic mutation profile of tumor specimen TARGET-10-PARJYV-09A (aliquot TARGET-10-PARJYV-09A-01D) from TARGET case TARGET-10-PARJYV, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 11.9 years (4,333 days).
Specimen TARGET-10-PARJYV-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1feaa70a-a7ae-40e1-a5a7-02bc407278be.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARJYV-10A (Blood Derived Normal), aliquot TARGET-10-PARJYV-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e68add38-8150-4e08-af81-850b4bb3fd9a

The open-access MAF lists 41 somatic variants for this specimen: 25 protein-altering or splice-affecting, 6 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 6, Intron 4, 3'UTR 3, Nonsense Mutation 2, Splice Site 1, 3'Flank 1, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GATM | c.505C>T p.R169* | Nonsense Mutation (SNP) | VAF 16/29 reads (55%) | catalogued as rs397514708, CM104279; ClinVar: pathogenic; called by muse, mutect2, varscan2
- JAK1 | c.2729T>C p.L910P | Missense Mutation (SNP) | VAF 25/153 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61090359; called by muse, mutect2, varscan2
- ADAMTSL5 | c.910C>T p.R304C | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.409); catalogued as rs763835744, COSV57860165; called by muse, mutect2, varscan2
- AP3B2 | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 39/81 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1233321722; called by muse, mutect2, varscan2
- DPH1 | c.350C>T p.A117V | Missense Mutation (SNP) | VAF 51/118 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as rs373595133; called by muse, mutect2, varscan2
- EFR3A | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT tolerated (0.64); PolyPhen benign (0.013); catalogued as rs1326472927; called by muse, mutect2, varscan2
- HEATR1 | c.6119G>A p.R2040Q | Missense Mutation (SNP) | VAF 4/67 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs1345230897; called by muse, mutect2
- METTL27 | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 59/142 reads (42%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as rs371452591; called by muse, mutect2, varscan2
- MUC17 | c.191C>T p.A64V | Missense Mutation (SNP) | VAF 42/120 reads (35%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.006); catalogued as rs761973973, COSV60281736; called by muse, mutect2, varscan2
- OXGR1 | c.659C>T p.T220M | Missense Mutation (SNP) | VAF 32/236 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs752266769; called by muse, mutect2, varscan2
- PAX5 | c.92G>A p.R31Q | Missense Mutation (SNP) | VAF 50/66 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV63904758; called by muse, mutect2, varscan2
- SEMA3C | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 30/156 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs765250284, COSV54843221; called by muse, mutect2, varscan2
- SETD2 | c.7541A>G p.H2514R | Missense Mutation (SNP) | VAF 20/149 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV57432757; called by muse, mutect2, varscan2
- STXBP4 | c.1240C>T p.R414* | Nonsense Mutation (SNP) | VAF 17/74 reads (23%) | catalogued as rs771237626, COSV64467519; called by muse, mutect2, varscan2
- ACOT11 | c.1631G>C p.C544S | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATAD5 | c.3998T>C p.I1333T | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- BRCA2 | c.2018A>C p.N673T | Missense Mutation (SNP) | VAF 46/112 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- DAAM1 | c.485T>A p.L162H | Missense Mutation (SNP) | VAF 88/180 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GRIK1 | c.221A>T p.N74I | Missense Mutation (SNP) | VAF 90/205 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- JAK1 | c.2413T>A p.F805I | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MAGT1 | c.130C>G p.L44V (on ENST00000618282 / NM_001367916.1; = p.L76V on NM_032121.5) | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- PTPN13 | c.2650+1G>C p.X884_splice | Splice Site (SNP) | VAF 22/113 reads (19%) | called by muse, mutect2, varscan2
- RABGGTB | c.211A>T p.I71F | Missense Mutation (SNP) | VAF 9/144 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); called by muse, mutect2
- SPTAN1 | c.907G>A p.D303N | Missense Mutation (SNP) | VAF 27/137 reads (20%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZEB2 | c.3215A>G p.Q1072R | Missense Mutation (SNP) | VAF 28/164 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- ACTN2 | c.762C>T p.H254= | Silent (SNP) | VAF 24/117 reads (21%) | catalogued as rs397516584, COSV63971828; ClinVar: likely benign; called by muse, mutect2, varscan2
- GRID1 | c.996C>T p.N332= | Silent (SNP) | VAF 24/59 reads (41%) | catalogued as rs368514571, COSV60016794, COSV60044062; called by muse, mutect2, varscan2
- HSPA12A | c.1821C>T p.H607= | Silent (SNP) | VAF 45/100 reads (45%) | catalogued as rs200665425, COSV65020713; called by muse, mutect2, varscan2
- SMAD2 | c.1071G>T p.V357= | Silent (SNP) | VAF 90/242 reads (37%) | called by muse, mutect2, varscan2
- TMEM132D | c.858G>T p.L286= | Silent (SNP) | VAF 12/101 reads (12%) | catalogued as COSV70598750; called by muse, mutect2, varscan2
- TRAV40 | c.87C>T p.T29= | Silent (SNP) | VAF 15/194 reads (8%) | catalogued as rs754720424; called by muse, mutect2
- AOC4P | chr17:42867260 C>T | 5'Flank (SNP) | VAF 22/56 reads (39%) | catalogued as rs527358581; called by muse, mutect2, varscan2
- GPC5 | c.*7T>A | 3'UTR (SNP) | VAF 51/113 reads (45%) | catalogued as COSV100992565; called by muse, mutect2, varscan2
- LCN12 | c.550+281_550+323del | Intron (DEL) | VAF 4/29 reads (14%) | catalogued as rs760050215; called by muse*, mutect2
- MEA1 | c.29-16_29-12del | Intron (DEL) | VAF 11/48 reads (23%) | called by mutect2, pindel, varscan2
- MIR524 | n.59G>A | RNA (SNP) | VAF 58/129 reads (45%) | catalogued as rs747268431; called by muse, mutect2, varscan2
- MMP11 | c.1075+233C>T | Intron (SNP) | VAF 7/17 reads (41%) | called by muse, mutect2, varscan2
- PPT2 | c.542-47C>T | Intron (SNP) | VAF 14/34 reads (41%) | called by muse, mutect2, varscan2
- SOHLH1 | c.*129G>A | 3'UTR (SNP) | VAF 4/20 reads (20%) | catalogued as rs899620298; called by muse, mutect2
- TRAJ12 | chr14:22536144 ins GGAA | 3'Flank (INS) | VAF 22/160 reads (14%) | called by mutect2, pindel*, varscan2
- ZNF594 | c.*424A>G | 3'UTR (SNP) | VAF 138/296 reads (47%) | called by muse, mutect2, varscan2
